Somatic mutation profile of tumor specimen TCGA-VS-A9V2-01A (aliquot TCGA-VS-A9V2-01A-11D-A42O-09) from TCGA case TCGA-VS-A9V2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 29.1 years (10,637 days).
Specimen TCGA-VS-A9V2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9edcd0d7-e766-42a4-8199-72ae99ff517b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V2-10A (Blood Derived Normal), aliquot TCGA-VS-A9V2-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df72bc5-e3b2-4bf6-ad12-790e8172f955

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 33, Silent 13, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as rs201701737, COSV53902646; called by muse, mutect2, varscan2
- AP3D1 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV100642662; called by muse, mutect2, varscan2
- APOB | c.4104C>G p.N1368K | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265562; called by muse, mutect2
- AVPR1A | c.1192A>G p.T398A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.101); catalogued as COSV100146850; called by muse, mutect2, varscan2
- C16orf78 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100147727; called by muse, mutect2, varscan2
- COL4A1 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1513273, COSV65431047; called by muse, mutect2, varscan2
- CTNND2 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.572); catalogued as rs1341007475, COSV100474055; called by muse, mutect2, varscan2
- CYP2E1 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV99428972; called by muse, mutect2, varscan2
- DACT1 | c.1732G>A p.V578I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1426512895, COSV60019271; called by muse, mutect2, varscan2
- ELP4 | c.776A>G p.Q259R (on ENST00000350638; = p.Q258R on NM_019040.5) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100635472; called by muse, mutect2
- FLRT2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781442004, COSV100420379; called by muse, mutect2, varscan2
- H2BC8 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99773224; called by muse, mutect2, varscan2
- IGFN1 | c.3317C>A p.P1106H (on ENST00000295591 / NM_001367841.1; = p.P3563H on NM_001164586.2) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99812216; called by muse, mutect2, varscan2
- KMT2C | c.6991G>A p.E2331K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV51454577; called by muse, mutect2, varscan2
- LTBP1 | c.1648G>A p.V550M (on ENST00000404816 / NM_206943.4; = p.V224M on NM_000627.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs767256539, COSV63185235; called by muse, mutect2, varscan2
- MEF2C | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV100425297; called by muse, mutect2, varscan2
- MSI1 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57456095, COSV99981518; called by muse, mutect2, varscan2
- MUC17 | c.5468C>A p.S1823Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100073134; called by muse, mutect2, varscan2
- NETO1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV100198690; called by muse, mutect2, varscan2
- NFKB2 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99192656; called by muse, mutect2, varscan2
- NLGN4X | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1051301935, COSV99321667; called by muse, mutect2, varscan2
- NOL10 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100630082; called by muse, mutect2, varscan2
- OLFML1 | c.637T>C p.W213R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100206495; called by muse, mutect2, varscan2
- PITPNM1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs763821608, COSV100711656, COSV100711754; called by muse, mutect2, varscan2
- POLA1 | c.3944G>T p.C1315F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100985412; called by muse, mutect2, varscan2
- SLC15A1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100918200; called by muse, mutect2, varscan2
- SLC2A1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs199639208; called by muse, mutect2, varscan2
- STK24 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs200464604, COSV64823712; called by muse, mutect2, varscan2
- TIE1 | c.2823T>A p.F941L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100992076; called by muse, mutect2, varscan2
- TTBK2 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99141516; called by muse, mutect2, varscan2
- ZC3H7B | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100687336; called by muse, mutect2, varscan2
- ZFYVE28 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs777916676, COSV99342906; called by muse, mutect2, varscan2
- ZNF672 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs1029050646, COSV60638073; called by muse, mutect2, varscan2
- AC004593.2 | c.735_745del p.S246Kfs*2 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- EPHB3 | c.463_467dup p.V157* | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- OR6A2 | c.730del p.S244Pfs*10 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CHD2 | c.924C>T p.L308= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100560691; called by muse, mutect2, varscan2
- CRYBG2 | c.801C>T p.G267= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- CYP11A1 | c.735C>A p.V245= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99166003; called by mutect2, varscan2
- ITGB8 | c.834A>G p.R278= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs368113666; called by mutect2, varscan2
- MYF6 | c.192G>A p.A64= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs773125073, COSV57350855; called by muse, varscan2
- PABPC5 | c.133C>A p.R45= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100442297, COSV57040266, COSV57041971; called by muse, mutect2, varscan2
- PROS1 | c.147C>A p.T49= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100820289; called by muse, mutect2, varscan2
- SCN7A | c.1632C>T p.F544= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV101313213; called by muse, mutect2, varscan2
- SLC4A2 | c.1803C>T p.A601= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100055327; called by muse, mutect2
- SP4 | c.153G>C p.L51= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99754444; called by muse, mutect2, varscan2
- SPATA31E1 | c.1476G>A p.Q492= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100350401; called by muse, mutect2, varscan2
- SS18L2 | c.141C>T p.C47= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs764845012, COSV99165271; called by muse, mutect2, varscan2
- TBC1D16 | c.618C>T p.A206= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1476935325, COSV100188031; called by muse, mutect2, varscan2
